Somatic mutation profile of tumor specimen MMRF_2721_1_BM_CD138pos (aliquot MMRF_2721_1_BM_CD138pos_T1_KHS5U_L14823) from MMRF case MMRF_2721, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 41.9 years (15,319 days).
Specimen MMRF_2721_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a5569787-d356-4532-84b9-4412b6e2948a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2721_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2721_1_PB_WBC_C2_KHS5U_L14824; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/93bdab43-319b-45d1-9bb2-0792e81ecf84

The open-access MAF lists 108 somatic variants for this specimen: 46 protein-altering or splice-affecting, 18 silent, 44 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 34, 3'UTR 19, Silent 18, Intron 10, 5'UTR 8, Nonsense Mutation 7, Frame Shift Del 4, RNA 4, 5'Flank 2, Splice Site 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 50/107 reads (47%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AP002748.5 | c.353C>T p.P118L | Missense Mutation (SNP) | VAF 110/400 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.121); catalogued as rs1479663514; called by muse, mutect2, varscan2
- ARSB | c.252C>G p.N84K | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.779); catalogued as rs963095623; called by muse, mutect2, varscan2
- CLIP1 | c.532G>A p.E178K | Missense Mutation (SNP) | VAF 54/111 reads (49%) | SIFT tolerated (0.13); PolyPhen benign (0.097); catalogued as rs539818652, COSV56805277; called by muse, mutect2, varscan2
- FAM13B | c.1886A>T p.D629V | Missense Mutation (SNP) | VAF 48/160 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.265); catalogued as rs1330092202; called by muse, mutect2, varscan2
- GRM7 | c.98G>A p.R33H | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV63129838; called by muse, mutect2, varscan2
- IGHV3-30 | c.238G>A p.A80T | Missense Mutation (SNP) | VAF 98/370 reads (26%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.125); catalogued as rs562635788; called by muse, varscan2
- IGLV4-60 | c.211C>G p.L71V | Missense Mutation (SNP) | VAF 72/166 reads (43%) | SIFT tolerated (0.98); PolyPhen benign (0.005); catalogued as rs375413070; called by muse, mutect2, varscan2
- KRTAP10-8 | c.497G>A p.C166Y | Missense Mutation (SNP) | VAF 113/187 reads (60%) | SIFT deleterious (0.01); PolyPhen benign (0.194); catalogued as rs1360429438; called by muse, mutect2, varscan2
- MMP17 | c.968+1G>A p.X323_splice | Splice Site (SNP) | VAF 26/52 reads (50%) | catalogued as rs756600031, COSV100862000; called by muse, mutect2, varscan2
- NLRP2 | c.1346C>T p.T449M | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.443); catalogued as rs144271525; called by muse, mutect2, varscan2
- PTPRS | c.1286C>T p.A429V | Missense Mutation (SNP) | VAF 23/119 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.817); catalogued as rs919253826, COSV53619310; called by muse, mutect2, varscan2
- RWDD2B | c.296C>T p.A99V | Missense Mutation (SNP) | VAF 202/296 reads (68%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs149192196; called by muse, mutect2, varscan2
- RYR1 | c.9277C>T p.R3093C | Missense Mutation (SNP) | VAF 71/263 reads (27%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.993); catalogued as rs1064797039; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RYR2 | c.13987C>T p.R4663* | Nonsense Mutation (SNP) | VAF 66/186 reads (35%) | catalogued as rs1398653043, COSV100772582; called by muse, mutect2, varscan2
- STAT3 | c.1027G>A p.V343I | Missense Mutation (SNP) | VAF 33/65 reads (51%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.76); catalogued as CM086673, CM127245, COSV52883684; called by muse, mutect2, varscan2
- TMEM200C | c.982G>T p.E328* | Nonsense Mutation (SNP) | VAF 13/28 reads (46%) | catalogued as COSV67310168; called by muse, mutect2, varscan2
- UBOX5 | c.1612C>T p.R538W | Missense Mutation (SNP) | VAF 22/41 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs950917852, COSV99418347; called by muse, mutect2, varscan2
- ZMPSTE24 | c.320G>A p.R107Q | Missense Mutation (SNP) | VAF 85/197 reads (43%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs372348936; called by muse, mutect2, varscan2
- ZNF235 | c.1751C>T p.S584L | Missense Mutation (SNP) | VAF 92/349 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.73); catalogued as COSV99349225; called by muse, mutect2, varscan2
- ZNF281 | c.2116C>G p.P706A | Missense Mutation (SNP) | VAF 22/228 reads (10%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as COSV54167345; called by muse, mutect2
- ADAMTS16 | c.853C>T p.H285Y | Missense Mutation (SNP) | VAF 61/105 reads (58%) | SIFT deleterious (0.05); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ARHGAP4 | c.1573G>T p.E525* | Nonsense Mutation (SNP) | VAF 8/148 reads (5%) | called by muse, mutect2
- ARSB | c.46C>G p.R16G | Missense Mutation (SNP) | VAF 27/43 reads (63%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); called by muse, mutect2, varscan2
- CHIC1 | c.106T>G p.S36A | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.01); called by muse, mutect2
- DNAH8 | c.13229G>T p.W4410L | Missense Mutation (SNP) | VAF 41/101 reads (41%) | SIFT tolerated (0.12); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DVL1 | c.570C>G p.S190R | Missense Mutation (SNP) | VAF 47/94 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- GRIP1 | c.1912G>A p.D638N (on ENST00000359742 / NM_001379345.1; = p.D586N on NM_021150.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/260 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.529); called by muse, mutect2
- GRM5 | c.1729G>C p.D577H | Missense Mutation (SNP) | VAF 14/116 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- IGHV2-70D | c.155_156del p.G52Dfs*21 | Frame Shift Del (DEL) | VAF 40/42 reads (95%) | called by mutect2, varscan2*
- IGLL5 | c.521A>T p.Y174F | Missense Mutation (SNP) | VAF 25/28 reads (89%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.738); called by muse, mutect2, varscan2
- MYOC | c.1220A>G p.N407S | Missense Mutation (SNP) | VAF 80/176 reads (45%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.785); called by muse, mutect2, varscan2
- OR8D4 | c.52A>G p.T18A | Missense Mutation (SNP) | VAF 21/437 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); called by muse, mutect2
- PDE3B | c.3243del p.K1081Nfs*24 | Frame Shift Del (DEL) | VAF 60/253 reads (24%) | called by mutect2, pindel, varscan2
- PDE8A | c.2419G>T p.D807Y | Missense Mutation (SNP) | VAF 57/174 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- PPP4R3A | c.2326G>T p.G776* (on ENST00000554943 / NM_001366432.1; = p.G763* on NM_001284280.1) | Nonsense Mutation (SNP) | VAF 39/98 reads (40%) | called by muse, mutect2, varscan2
- SMG1 | c.5574T>A p.Y1858* | Nonsense Mutation (SNP) | VAF 47/94 reads (50%) | called by muse, mutect2, varscan2
- SP140 | c.2140G>T p.E714* | Nonsense Mutation (SNP) | VAF 54/102 reads (53%) | called by muse, mutect2, varscan2
- SUPT16H | c.1459G>C p.E487Q | Missense Mutation (SNP) | VAF 4/100 reads (4%) | SIFT tolerated (0.16); PolyPhen benign (0.031); called by muse, mutect2
- TCF20 | c.5723A>C p.Y1908S | Missense Mutation (SNP) | VAF 48/136 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- TENT5C | c.524G>C p.R175P | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); called by muse, mutect2, varscan2
- TENT5C | c.803_822del p.R268Lfs*9 | Frame Shift Del (DEL) | VAF 30/68 reads (44%) | called by pindel, varscan2
- TENT5C | c.872_876del p.Y291Sfs*6 | Frame Shift Del (DEL) | VAF 22/90 reads (24%) | called by pindel, varscan2
- YY2 | c.538G>T p.E180* | Nonsense Mutation (SNP) | VAF 32/80 reads (40%) | called by muse, mutect2, varscan2
- ZNF175 | c.1841C>A p.P614H | Missense Mutation (SNP) | VAF 11/266 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2
- ZNF711 | c.1236A>C p.K412N | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ADRB1 | c.1077C>T p.F359= | Silent (SNP) | VAF 22/165 reads (13%) | catalogued as rs776634546; called by muse, mutect2, varscan2
- AFDN | c.4980G>A p.L1660= (on ENST00000447894 / NM_001366320.1; = p.L1643= on NM_001207008.1) | Silent (SNP) | VAF 37/77 reads (48%) | called by muse, mutect2, varscan2
- DAB2IP | c.903G>T p.V301= (on ENST00000408936; = p.V273= on NM_032552.3) | Silent (SNP) | VAF 207/416 reads (50%) | called by muse, mutect2, varscan2
- DNAJC2 | c.180C>T p.S60= | Silent (SNP) | VAF 122/276 reads (44%) | catalogued as rs371816384; called by muse, mutect2, varscan2
- GPR161 | c.600C>A p.P200= | Silent (SNP) | VAF 74/161 reads (46%) | called by muse, mutect2, varscan2
- KNL1 | c.1041G>A p.L347= (on ENST00000346991 / NM_170589.5; = p.L321= on NM_144508.5) | Silent (SNP) | VAF 147/501 reads (29%) | called by muse, mutect2, varscan2
- LPA | c.3324T>A p.A1108= | Silent (SNP) | VAF 29/58 reads (50%) | called by muse, mutect2, varscan2
- MAGEB3 | c.702T>C p.D234= | Silent (SNP) | VAF 55/100 reads (55%) | called by muse, mutect2, varscan2
- MYOM1 | c.3069C>T p.S1023= | Silent (SNP) | VAF 7/50 reads (14%) | catalogued as rs747906321, COSV99868050; ClinVar: likely benign; called by muse, mutect2, varscan2
- NPTX2 | c.711C>T p.Y237= | Silent (SNP) | VAF 14/166 reads (8%) | catalogued as rs573416055, COSV55717304, COSV55717885; called by muse, mutect2
- OR2T3 | c.12G>T p.G4= | Silent (SNP) | VAF 11/264 reads (4%) | called by muse, mutect2
- PDHA2 | c.978G>A p.K326= | Silent (SNP) | VAF 91/187 reads (49%) | called by muse, mutect2, varscan2
- PNPLA3 | c.268T>C p.L90= | Silent (SNP) | VAF 80/145 reads (55%) | called by muse, mutect2, varscan2
- SYNE1 | c.25491C>T p.A8497= (on ENST00000367255 / NM_182961.4; = p.A8449= on NM_033071.3) | Silent (SNP) | VAF 31/64 reads (48%) | called by muse, mutect2, varscan2
- THOC2 | c.27C>T p.P9= | Silent (SNP) | VAF 12/341 reads (4%) | catalogued as rs1029803929, COSV55549924; called by muse, mutect2
- TOR4A | c.435G>A p.A145= | Silent (SNP) | VAF 78/149 reads (52%) | catalogued as COSV62626751; called by muse, mutect2, varscan2
- TTN | c.97125G>C p.L32375= (on ENST00000591111; = p.L24951= on NM_003319.4) | Silent (SNP) | VAF 10/158 reads (6%) | called by muse, mutect2
- YY2 | c.537G>T p.L179= | Silent (SNP) | VAF 31/79 reads (39%) | catalogued as COSV63410852; called by muse, mutect2, varscan2
- AL162231.1 | c.48-62del | Intron (DEL) | VAF 4/11 reads (36%) | called by mutect2, varscan2
- AL353743.4 | n.756T>C | RNA (SNP) | VAF 63/209 reads (30%) | called by muse, mutect2, varscan2
- ALDH9A1 | c.-76C>T | 5'UTR (SNP) | VAF 11/36 reads (31%) | called by muse, mutect2, varscan2
- B4GALT3 | c.-161+345A>G | Intron (SNP) | VAF 33/73 reads (45%) | called by muse, mutect2, varscan2
- BCCIP | c.850+723C>T | Intron (SNP) | VAF 41/90 reads (46%) | catalogued as rs149044729; called by muse, mutect2, varscan2
- BIRC3 | c.-1471A>G | 5'UTR (SNP) | VAF 33/95 reads (35%) | called by muse, mutect2, varscan2
- BNC2 | c.2639+4111G>A | Intron (SNP) | VAF 98/189 reads (52%) | catalogued as rs965327727; called by muse, mutect2, varscan2
- BRWD1 | c.*2282T>C | 3'UTR (SNP) | VAF 30/91 reads (33%) | catalogued as rs764695490; called by muse, mutect2, varscan2
- C10orf105 | c.*3560G>A | 3'UTR (SNP) | VAF 22/42 reads (52%) | called by muse, mutect2, varscan2
- C4orf50 | c.*2475-25089A>T | Intron (SNP) | VAF 38/77 reads (49%) | called by muse, mutect2, varscan2
- CACNA1E | c.*2272C>A | 3'UTR (SNP) | VAF 42/85 reads (49%) | called by muse, mutect2, varscan2
- CBL | c.*376T>C | 3'UTR (SNP) | VAF 35/113 reads (31%) | called by muse, mutect2, varscan2
- CCNJ | c.*2353T>G | 3'UTR (SNP) | VAF 10/23 reads (43%) | called by muse, mutect2
- CDCA5 | c.46+18G>A | Intron (SNP) | VAF 8/225 reads (4%) | called by muse, mutect2
- DACH2 | c.1751-4083T>C | Intron (SNP) | VAF 12/41 reads (29%) | called by muse, mutect2, varscan2
- DBNL | chr7:44044678 A>C | 5'Flank (SNP) | VAF 13/36 reads (36%) | called by muse, mutect2, varscan2
- DNAH11 | c.*91T>A | 3'UTR (SNP) | VAF 93/211 reads (44%) | catalogued as rs1322889796; called by muse, mutect2, varscan2
- EGFR | c.-89G>T | 5'UTR (SNP) | VAF 17/32 reads (53%) | called by muse, mutect2, varscan2
- ENY2 | c.*1985T>G | 3'UTR (SNP) | VAF 10/56 reads (18%) | called by muse, mutect2, varscan2
- HTR1A | c.-338G>A | 5'UTR (SNP) | VAF 52/140 reads (37%) | called by muse, mutect2, varscan2
- IGFBP2 | c.*142C>T | 3'UTR (SNP) | VAF 33/89 reads (37%) | catalogued as rs1161851425; called by muse, mutect2, varscan2
- KIF26A | chr14:104180718 C>T | 3'Flank (SNP) | VAF 7/96 reads (7%) | catalogued as rs973059365; called by muse, mutect2
- MIR124-2 | chr8:64378335 C>T | 5'Flank (SNP) | VAF 36/56 reads (64%) | called by muse, mutect2, varscan2
- MRPS27 | c.281+184T>C | Intron (SNP) | VAF 25/66 reads (38%) | called by muse, mutect2, varscan2
- MYO1H | c.*683G>C | 3'UTR (SNP) | VAF 13/30 reads (43%) | called by muse, mutect2, varscan2
- MYO9A | c.*1102_*1127delinsTTTATCTTCCTTTTCTCAGACTATCA | 3'UTR (ONP) | VAF 13/101 reads (13%) | called by pindel, varscan2*
- NFIA | c.*5570G>A | 3'UTR (SNP) | VAF 32/75 reads (43%) | called by muse, mutect2, varscan2
- PCBP3 | c.675+14C>A | Intron (SNP) | VAF 34/125 reads (27%) | called by muse, varscan2
- PCGF3 | c.*694G>A | 3'UTR (SNP) | VAF 68/134 reads (51%) | catalogued as rs1422589447; called by muse, mutect2, varscan2
- PSG3 | c.-2C>T | 5'UTR (SNP) | VAF 53/255 reads (21%) | catalogued as rs747868569; called by muse, mutect2, varscan2
- PSIP1 | c.*1368T>A | 3'UTR (SNP) | VAF 53/130 reads (41%) | called by muse, mutect2, varscan2
- RASSF6 | c.-117A>G | 5'UTR (SNP) | VAF 51/119 reads (43%) | called by muse, mutect2, varscan2
- RCBTB1 | c.*2142C>T | 3'UTR (SNP) | VAF 28/62 reads (45%) | catalogued as rs372400658; called by muse, mutect2, varscan2
- SLC22A15 | c.*370C>A | 3'UTR (SNP) | VAF 21/47 reads (45%) | called by muse, mutect2, varscan2
- SPATA31D5P | n.2399T>C | RNA (SNP) | VAF 87/369 reads (24%) | catalogued as rs1276898876; called by muse, mutect2, varscan2
- SRRM4 | c.*5760A>C | 3'UTR (SNP) | VAF 21/50 reads (42%) | called by muse, mutect2, varscan2
- SSTR4 | c.*98C>T | 3'UTR (SNP) | VAF 8/115 reads (7%) | called by muse, mutect2
- TNR | c.*403C>T | 3'UTR (SNP) | VAF 32/57 reads (56%) | called by muse, mutect2, varscan2
- UBQLN1 | c.-21G>A | 5'UTR (SNP) | VAF 4/46 reads (9%) | catalogued as rs1564176443, COSV57406606; called by muse, mutect2
- XIST | n.8287G>T | RNA (SNP) | VAF 20/224 reads (9%) | catalogued as rs756943951; called by muse, mutect2
- ZNF232 | c.-510T>C | 5'UTR (SNP) | VAF 28/58 reads (48%) | called by muse, mutect2
- ZNF354A | c.161-705G>T | Intron (SNP) | VAF 8/131 reads (6%) | called by muse, mutect2
- ZNF611 | c.*232G>T | 3'UTR (SNP) | VAF 29/510 reads (6%) | catalogued as COSV60544242; called by muse, mutect2
- ZNF788P | n.234C>T | RNA (SNP) | VAF 5/26 reads (19%) | catalogued as rs750648585; called by muse, varscan2
